Somatic mutation profile of tumor specimen C3N-00738-01 (aliquot CPT0112060009) from CPTAC case C3N-00738, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G1; Age at diagnosis: 70.9 years (25,891 days).
Specimen C3N-00738-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bd9c2ef4-2890-4f34-ba3f-6388c49aefe6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00738-31 (Blood Derived Normal), aliquot CPT0112180002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/69a675f7-e284-4d1b-bd5d-9dfe1899e0e8

The open-access MAF lists 216 somatic variants for this specimen: 142 protein-altering or splice-affecting, 46 silent, 28 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 121, Silent 46, Intron 13, Nonsense Mutation 9, RNA 8, Frame Shift Del 5, Splice Site 4, 5'UTR 4, 3'UTR 1, Frame Shift Ins 1, Nonstop Mutation 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC11 | c.1137C>A p.C379* | Nonsense Mutation (SNP) | VAF 23/169 reads (14%) | catalogued as rs377586143; called by muse, mutect2, varscan2
- ACKR1 | c.383T>C p.L128P | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as CD142757; called by muse, mutect2
- AGMO | c.560C>A p.A187D | Missense Mutation (SNP) | VAF 14/168 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as COSV61121545; called by muse, mutect2
- AL645922.1 | c.3430C>T p.R1144W | Missense Mutation (SNP) | VAF 29/492 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs911687564, COSV100964060; called by muse, mutect2
- ANKRD34B | c.1319G>T p.S440I | Missense Mutation (SNP) | VAF 22/199 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.055); catalogued as COSV58614046; called by muse, mutect2, varscan2
- AP3D1 | c.1853C>T p.P618L | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.728); catalogued as COSV100642821; called by muse, varscan2
- ARHGEF40 | c.4241G>A p.R1414K | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as COSV100069960; called by muse, mutect2
- ARRB2 | c.949G>A p.G317R | Missense Mutation (SNP) | VAF 22/248 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52617481; called by muse, mutect2
- ATG16L2 | c.1595del p.R532Lfs*76 | Frame Shift Del (DEL) | VAF 18/200 reads (9%) | catalogued as COSV58362481; called by mutect2, pindel
- C1orf167 | c.2162G>T p.W721L | Missense Mutation (SNP) | VAF 14/180 reads (8%) | SIFT deleterious (0); catalogued as rs1461132699; called by muse, mutect2
- CEP19 | c.-71+1G>T | Splice Site (SNP) | VAF 8/168 reads (5%) | catalogued as COSV99582211; called by muse, mutect2
- CNGB1 | c.2959G>T p.D987Y | Missense Mutation (SNP) | VAF 58/507 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768408396; called by muse, mutect2, varscan2
- CRLF2 | c.44T>C p.L15P | Missense Mutation (SNP) | VAF 16/292 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.166); catalogued as rs1206189838; called by muse, mutect2
- CSMD3 | c.10172G>T p.R3391L (on ENST00000297405 / NM_001363185.1; = p.R3222L on NM_052900.3) | Missense Mutation (SNP) | VAF 22/276 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as rs750171856, COSV52100044, COSV52183749; called by muse, mutect2
- FGF23 | c.41G>C p.C14S | Missense Mutation (SNP) | VAF 24/266 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV99426438; called by muse, mutect2
- FSHR | c.1004A>G p.Y335C | Missense Mutation (SNP) | VAF 34/360 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1014806626; called by muse, mutect2, varscan2
- GCKR | c.31A>G p.I11V | Missense Mutation (SNP) | VAF 40/481 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.253); catalogued as rs755400366, COSV99254112; called by muse, mutect2
- GPATCH8 | c.3545del p.P1182Qfs*22 | Frame Shift Del (DEL) | VAF 5/45 reads (11%) | catalogued as COSV59193518; called by mutect2, pindel, varscan2
- HIP1R | c.2587G>C p.A863P | Missense Mutation (SNP) | VAF 12/178 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53442467; called by muse, mutect2
- HMCN1 | c.12274G>C p.V4092L | Missense Mutation (SNP) | VAF 30/367 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.055); catalogued as COSV54874349; called by muse, mutect2
- HOXC12 | c.203A>T p.Y68F | Missense Mutation (SNP) | VAF 26/364 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.13); catalogued as COSV99678657; called by muse, mutect2
- KIAA1210 | c.2113C>A p.Q705K | Missense Mutation (SNP) | VAF 20/250 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV68177078; called by muse, mutect2
- LRIF1 | c.1520T>C p.I507T | Missense Mutation (SNP) | VAF 16/219 reads (7%) | SIFT tolerated (0.61); PolyPhen benign (0.354); catalogued as rs1325468836; called by muse, mutect2
- MPEG1 | c.1574C>T p.A525V | Missense Mutation (SNP) | VAF 17/206 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.026); catalogued as rs199736754, COSV57094621; called by muse, mutect2
- MSR1 | c.1136G>A p.W379* | Nonsense Mutation (SNP) | VAF 14/308 reads (5%) | catalogued as COSV50508229; called by muse, mutect2
- MUC13 | c.367G>T p.A123S | Missense Mutation (SNP) | VAF 46/433 reads (11%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as rs762619425; called by muse, mutect2, varscan2
- NDUFA12 | c.286G>T p.D96Y | Missense Mutation (SNP) | VAF 42/354 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.873); catalogued as COSV59845635; called by mutect2, varscan2
- NKAPL | c.1058G>A p.R353Q | Missense Mutation (SNP) | VAF 16/254 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59199582; called by muse, mutect2
- OR10Z1 | c.88T>A p.L30M | Missense Mutation (SNP) | VAF 40/262 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.045); catalogued as COSV63526680; called by muse, mutect2, varscan2
- OR2AK2 | c.70A>T p.N24Y | Missense Mutation (SNP) | VAF 22/199 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.851); catalogued as COSV63552775; called by muse, mutect2, varscan2
- OR52D1 | c.537C>A p.H179Q | Missense Mutation (SNP) | VAF 21/230 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59488306; called by muse, mutect2
- OR56B4 | c.345C>G p.C115W | Missense Mutation (SNP) | VAF 28/274 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV100337711; called by muse, mutect2, varscan2
- OR5H6 | c.406T>C p.Y136H (on ENST00000642105; = p.Y120H on NM_001005479.2) | Missense Mutation (SNP) | VAF 10/222 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV67352059; called by muse, mutect2
- OR5M8 | c.668C>T p.A223V | Missense Mutation (SNP) | VAF 18/212 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs1247546487; called by muse, mutect2
- PABPC5 | c.352G>T p.D118Y | Missense Mutation (SNP) | VAF 22/272 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57040463; called by muse, mutect2
- PACRGL | c.365A>T p.E122V | Missense Mutation (SNP) | VAF 19/165 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54845271; called by muse, mutect2, varscan2
- PCDHGA7 | c.107C>G p.S36W | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.907); catalogued as rs751850819, COSV53951993; called by muse, mutect2, varscan2
- PGK1 | c.197G>C p.R66P | Missense Mutation (SNP) | VAF 28/360 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100965359; called by muse, mutect2
- PMM1 | c.622G>T p.D208Y | Missense Mutation (SNP) | VAF 17/193 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs1279835895; called by muse, mutect2
- PPP3CA | c.1414G>T p.E472* | Nonsense Mutation (SNP) | VAF 14/130 reads (11%) | catalogued as COSV59923629; called by muse, mutect2
- PSG9 | c.744C>G p.N248K | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); catalogued as rs1476259630; called by muse, mutect2
- RTP3 | c.66G>T p.W22C | Missense Mutation (SNP) | VAF 36/270 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.072); catalogued as COSV56124400; called by muse, mutect2, varscan2
- SAMD9L | c.1293C>G p.H431Q | Missense Mutation (SNP) | VAF 24/204 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.029); catalogued as rs771056187; called by muse, mutect2, varscan2
- SLC39A4 | c.1283C>T p.P428L (on ENST00000301305 / NM_001374839.1; = p.P403L on NM_017767.3) | Missense Mutation (SNP) | VAF 60/542 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.031); catalogued as rs1279022205; called by muse, mutect2, varscan2
- SPEN | c.8393C>T p.A2798V | Missense Mutation (SNP) | VAF 10/109 reads (9%) | SIFT tolerated (0.5); PolyPhen benign (0.059); catalogued as rs772466830; called by muse, mutect2
- SPTA1 | c.5467C>T p.Q1823* | Nonsense Mutation (SNP) | VAF 55/518 reads (11%) | catalogued as rs1557937967; called by muse, mutect2, varscan2
- SRRM2 | c.5750del p.P1917Qfs*2 | Frame Shift Del (DEL) | VAF 20/196 reads (10%) | catalogued as COSV57073209; called by mutect2, pindel
- SV2A | c.37C>A p.R13S | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.097); catalogued as COSV100975075; called by muse, mutect2
- TCF23 | c.218G>C p.G73A | Missense Mutation (SNP) | VAF 6/134 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.096); catalogued as COSV99940294; called by muse, mutect2
- TNN | c.890C>A p.P297H | Missense Mutation (SNP) | VAF 29/398 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV53426653; called by muse, mutect2
- UPF3A | c.1160G>T p.R387I | Missense Mutation (SNP) | VAF 13/160 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.361); catalogued as COSV60896030; called by muse, mutect2
- USP34 | c.6079G>A p.E2027K | Missense Mutation (SNP) | VAF 11/223 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.534); catalogued as COSV104433667; called by muse, mutect2
- VNN1 | c.1272G>C p.M424I | Missense Mutation (SNP) | VAF 11/268 reads (4%) | SIFT tolerated (0.31); PolyPhen benign (0.015); catalogued as COSV63390315; called by muse, mutect2
- ZNF483 | c.995A>T p.Y332F | Missense Mutation (SNP) | VAF 21/188 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.073); catalogued as rs1374013096; called by muse, mutect2, varscan2
- ADAMTS12 | c.1190+1del p.X397_splice | Splice Site (DEL) | VAF 16/98 reads (16%) | called by mutect2, pindel
- ADGRA3 | c.3966A>T p.*1322Yext*6 | Nonstop Mutation (SNP) | VAF 11/70 reads (16%) | called by muse, mutect2, varscan2
- AIPL1 | c.712C>T p.Q238* | Nonsense Mutation (SNP) | VAF 26/358 reads (7%) | called by muse, mutect2
- ANHX | c.274C>A p.Q92K | Missense Mutation (SNP) | VAF 16/216 reads (7%) | SIFT tolerated (0.88); PolyPhen benign (0.006); called by muse, mutect2
- ANKDD1B | c.1112T>A p.L371Q | Missense Mutation (SNP) | VAF 22/189 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- AQP10 | c.652G>T p.D218Y | Missense Mutation (SNP) | VAF 23/299 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ARMCX4 | c.783A>T p.K261N (on ENST00000433011; = p.K157N on NM_001256155.2) | Missense Mutation (SNP) | VAF 16/170 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.25); called by muse, mutect2
- ATL3 | c.652C>G p.P218A | Missense Mutation (SNP) | VAF 25/276 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.406); called by muse, mutect2
- AVPR2 | c.437T>A p.L146Q | Missense Mutation (SNP) | VAF 60/590 reads (10%) | SIFT tolerated (0.51); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- B4GALNT4 | c.2250C>G p.D750E | Missense Mutation (SNP) | VAF 11/115 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- BAHCC1 | c.3664G>T p.E1222* | Nonsense Mutation (SNP) | VAF 8/116 reads (7%) | called by muse, mutect2
- CBLN4 | c.432A>C p.K144N | Missense Mutation (SNP) | VAF 33/294 reads (11%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.522); called by muse, mutect2, varscan2
- CC2D1B | c.191_212del p.K64Rfs*36 | Frame Shift Del (DEL) | VAF 16/184 reads (9%) | called by mutect2, pindel
- CDH20 | c.736G>T p.D246Y | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CENPB | c.149G>T p.R50L | Missense Mutation (SNP) | VAF 20/174 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.377); called by muse, mutect2, varscan2
- CNTNAP2 | c.1291G>T p.V431L | Missense Mutation (SNP) | VAF 37/334 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- COL4A1 | c.3119C>T p.P1040L | Missense Mutation (SNP) | VAF 36/478 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.888); called by muse, mutect2
- CPN1 | c.65C>A p.T22N | Missense Mutation (SNP) | VAF 46/468 reads (10%) | SIFT tolerated (0.49); PolyPhen benign (0.003); called by muse, mutect2
- CREBBP | c.2672del p.P891Lfs*36 | Frame Shift Del (DEL) | VAF 30/327 reads (9%) | called by mutect2, pindel, varscan2
- CTH | c.47A>T p.Q16L | Missense Mutation (SNP) | VAF 44/484 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.011); called by muse, mutect2
- DGKK | c.3355A>G p.I1119V | Missense Mutation (SNP) | VAF 16/245 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- DGKK | c.2723A>G p.Y908C | Missense Mutation (SNP) | VAF 17/221 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); called by muse, mutect2
- DOCK10 | c.5750A>T p.Y1917F | Missense Mutation (SNP) | VAF 24/248 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2
- EIF3CL | c.949A>T p.K317* | Nonsense Mutation (SNP) | VAF 20/254 reads (8%) | called by muse, mutect2
- EPS8L3 | c.854T>G p.I285S | Missense Mutation (SNP) | VAF 34/348 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.051); called by muse, mutect2
- EXOG | c.248C>G p.S83C | Missense Mutation (SNP) | VAF 24/220 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.12); called by muse, mutect2
- F5 | c.3250C>T p.Q1084* | Nonsense Mutation (SNP) | VAF 18/198 reads (9%) | called by muse, mutect2
- FAM181A | c.740C>A p.S247Y | Missense Mutation (SNP) | VAF 32/432 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.323); called by muse, mutect2
- FASTKD2 | c.874G>T p.G292* | Nonsense Mutation (SNP) | VAF 40/402 reads (10%) | called by muse, mutect2
- FIG4 | c.158A>G p.D53G | Missense Mutation (SNP) | VAF 12/231 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2
- FLG2 | c.6337G>A p.V2113M | Missense Mutation (SNP) | VAF 39/436 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.946); called by muse, mutect2
- GABRE | c.484A>T p.R162W | Missense Mutation (SNP) | VAF 20/262 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2
- GBX2 | c.196C>G p.P66A | Missense Mutation (SNP) | VAF 9/103 reads (9%) | SIFT tolerated (0.78); PolyPhen benign (0.099); called by muse, mutect2
- GLDC | c.862-4C>G | Splice Region (SNP) | VAF 34/362 reads (9%) | called by muse, mutect2
- GSDME | c.554G>A p.G185D | Missense Mutation (SNP) | VAF 20/354 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); called by muse, mutect2
- HDGFL2 | c.137G>A p.G46D | Missense Mutation (SNP) | VAF 25/270 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HTRA3 | c.778G>T p.G260C | Missense Mutation (SNP) | VAF 29/336 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- IGHD | c.1180T>A p.Y394N | Missense Mutation (SNP) | VAF 40/365 reads (11%) | SIFT tolerated, low confidence (0.36); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- IGHV6-1 | c.218C>A p.T73K | Missense Mutation (SNP) | VAF 30/386 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.641); called by muse, mutect2
- INTS1 | c.1793C>T p.P598L | Missense Mutation (SNP) | VAF 10/123 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.287); called by muse, mutect2
- KCNJ13 | c.-17+2T>G | Splice Site (SNP) | VAF 18/220 reads (8%) | called by muse, mutect2
- KCNN4 | c.176T>A p.F59Y | Missense Mutation (SNP) | VAF 10/156 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.197); called by muse, mutect2
- LINGO4 | c.735C>A p.D245E | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT tolerated (0.68); PolyPhen benign (0); called by muse, mutect2
- MARCHF1 | c.284C>A p.T95K (on ENST00000274056; = p.T78K on NM_017923.4) | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- MECP2 | c.265C>A p.R89S | Missense Mutation (SNP) | VAF 16/140 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- MINK1 | c.58G>T p.D20Y | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MLH1 | c.933G>C p.K311N | Missense Mutation (SNP) | VAF 17/264 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MMP16 | c.796C>A p.P266T | Missense Mutation (SNP) | VAF 22/212 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MPHOSPH9 | c.3497C>T p.S1166L | Missense Mutation (SNP) | VAF 10/149 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.976); called by muse, mutect2
- NBPF25P | n.950+1G>T | Splice Site (SNP) | VAF 22/869 reads (3%) | called by muse, mutect2
- NEUROG1 | c.401T>A p.L134Q | Missense Mutation (SNP) | VAF 23/274 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NEUROG2 | c.377A>T p.H126L | Missense Mutation (SNP) | VAF 27/560 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NPNT | c.310T>G p.C104G | Missense Mutation (SNP) | VAF 17/202 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NSD1 | c.2354C>T p.P785L | Missense Mutation (SNP) | VAF 27/237 reads (11%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- NSD1 | c.5504A>T p.K1835I | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); called by muse, varscan2
- NSMAF | c.1586T>A p.V529E | Missense Mutation (SNP) | VAF 17/152 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); called by muse, mutect2, varscan2
- OR12D2 | c.808G>T p.D270Y | Missense Mutation (SNP) | VAF 24/388 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2
- OR1G1 | c.329T>G p.L110R | Missense Mutation (SNP) | VAF 34/311 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.4); called by muse, mutect2, varscan2
- PABPC5 | c.976G>T p.G326W | Missense Mutation (SNP) | VAF 31/303 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDH17 | c.1444C>A p.H482N | Missense Mutation (SNP) | VAF 33/359 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.045); called by muse, mutect2
- PCDH19 | c.1666G>A p.V556I | Missense Mutation (SNP) | VAF 38/442 reads (9%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.513); called by muse, mutect2
- PCDHA1 | c.2011G>C p.E671Q | Missense Mutation (SNP) | VAF 18/247 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.439); called by muse, mutect2
- PCID2 | c.74G>A p.C25Y | Missense Mutation (SNP) | VAF 26/304 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.013); called by muse, mutect2
- PLB1 | c.830C>A p.T277N | Missense Mutation (SNP) | VAF 30/277 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.558); called by muse, mutect2, varscan2
- PROX2 | c.1405G>A p.D469N | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PRRG3 | c.479G>T p.G160V | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- PSME4 | c.1076G>T p.R359L | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.044); called by muse, mutect2
- PTCHD3 | c.836A>G p.N279S | Missense Mutation (SNP) | VAF 20/316 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.06); called by muse, mutect2
- PTPN9 | c.299A>G p.N100S | Missense Mutation (SNP) | VAF 25/166 reads (15%) | SIFT tolerated (0.61); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- PTPRT | c.1046A>G p.H349R | Missense Mutation (SNP) | VAF 34/365 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- RAD54L | c.2108T>A p.L703Q | Missense Mutation (SNP) | VAF 30/436 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); called by muse, mutect2
- RDX | c.1616G>T p.R539I | Missense Mutation (SNP) | VAF 40/395 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.412); called by muse, mutect2
- RUBCN | c.267dup p.W90Vfs*25 | Frame Shift Ins (INS) | VAF 40/474 reads (8%) | called by mutect2, pindel
- SLIT1 | c.2665G>A p.G889S | Missense Mutation (SNP) | VAF 11/194 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); called by muse, mutect2
- STOML3 | c.292T>G p.C98G | Missense Mutation (SNP) | VAF 20/167 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.425); called by muse, mutect2, varscan2
- STX11 | c.227T>A p.M76K | Missense Mutation (SNP) | VAF 18/342 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.718); called by muse, mutect2
- TAF1 | c.1192G>T p.G398W (on ENST00000373790 / NM_138923.4; = p.G419W on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/301 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TDRKH | c.1072G>C p.D358H | Missense Mutation (SNP) | VAF 9/104 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- TENM1 | c.2956C>A p.P986T | Missense Mutation (SNP) | VAF 30/344 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); called by muse, mutect2
- TSHZ1 | c.1691G>C p.S564T (on ENST00000580243 / NM_001308210.2; = p.S519T on NM_005786.6) | Missense Mutation (SNP) | VAF 15/175 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.15); called by muse, mutect2
- TTLL6 | c.1738G>A p.A580T (on ENST00000393382 / NM_001130918.3; = p.A273T on NM_173623.3) | Missense Mutation (SNP) | VAF 14/200 reads (7%) | SIFT tolerated (0.65); PolyPhen benign (0.012); called by muse, mutect2
- WDR72 | c.1357C>A p.P453T | Missense Mutation (SNP) | VAF 18/198 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.419); called by muse, mutect2
- YY2 | c.351G>T p.Q117H | Missense Mutation (SNP) | VAF 18/208 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); called by muse, mutect2
- ZNF329 | c.509G>A p.R170K | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2
- ZNF490 | c.181G>T p.D61Y | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ZNF595 | c.1187A>G p.Y396C | Missense Mutation (SNP) | VAF 19/181 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- ZNF804B | c.3889G>T p.G1297C | Missense Mutation (SNP) | VAF 27/249 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- ZNF841 | c.376T>C p.F126L (on ENST00000426391 / NM_001369830.1; = p.F242L on NM_001136499.1 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.026); called by muse, mutect2
- ADGRF1 | c.2586A>G p.T862= | Silent (SNP) | VAF 16/130 reads (12%) | called by muse, mutect2, varscan2
- ALLC | c.465C>G p.V155= | Silent (SNP) | VAF 19/259 reads (7%) | called by muse, mutect2
- APMAP | c.483G>T p.G161= | Silent (SNP) | VAF 17/186 reads (9%) | catalogued as rs1273385768, COSV99468042; called by muse, mutect2
- CABLES1 | c.1044T>C p.C348= (on ENST00000256925 / NM_001100619.2; = p.C83= on NM_138375.2) | Silent (SNP) | VAF 12/148 reads (8%) | called by muse, mutect2
- CELSR3 | c.6126T>C p.C2042= | Silent (SNP) | VAF 13/224 reads (6%) | called by muse, mutect2
- CFAP47 | c.1167C>A p.T389= | Silent (SNP) | VAF 9/119 reads (8%) | catalogued as rs1423237025; called by muse, mutect2
- COL20A1 | c.1356C>A p.G452= | Silent (SNP) | VAF 19/167 reads (11%) | called by muse, mutect2, varscan2
- CRLF2 | c.45G>T p.L15= | Silent (SNP) | VAF 16/294 reads (5%) | called by muse, mutect2
- CSMD1 | c.3546G>C p.L1182= (on ENST00000520002; = p.L1181= on NM_033225.6) | Silent (SNP) | VAF 10/191 reads (5%) | called by muse, mutect2
- DBNDD2 | c.519A>T p.A173= | Silent (SNP) | VAF 39/443 reads (9%) | called by muse, mutect2
- DDX60 | c.750A>C p.T250= | Silent (SNP) | VAF 12/134 reads (9%) | called by muse, mutect2
- DLC1 | c.921A>G p.P307= | Silent (SNP) | VAF 30/267 reads (11%) | called by muse, mutect2, varscan2
- DOCK9 | c.2823G>T p.T941= (on ENST00000376460 / NM_001366676.2; = p.T942= on NM_015296.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 20/330 reads (6%) | catalogued as COSV59631430; called by muse, mutect2
- EEF1A2 | c.738G>T p.L246= | Silent (SNP) | VAF 10/115 reads (9%) | called by muse, mutect2
- FAM117B | c.1512C>T p.F504= | Silent (SNP) | VAF 23/223 reads (10%) | called by muse, mutect2
- FAM9A | c.570A>G p.E190= | Silent (SNP) | VAF 14/194 reads (7%) | called by muse, mutect2
- FSTL5 | c.2118T>A p.L706= | Silent (SNP) | VAF 28/304 reads (9%) | called by muse, mutect2
- GLI4 | c.930C>T p.L310= | Silent (SNP) | VAF 12/208 reads (6%) | catalogued as COSV100391228; called by muse, mutect2
- GPR25 | c.787C>T p.L263= | Silent (SNP) | VAF 20/244 reads (8%) | called by muse, mutect2
- ICE1 | c.4161C>T p.N1387= | Silent (SNP) | VAF 14/210 reads (7%) | called by muse, mutect2
- IRAK3 | c.1263G>A p.L421= | Silent (SNP) | VAF 23/267 reads (9%) | called by muse, mutect2
- KCNT2 | c.2655G>T p.G885= | Silent (SNP) | VAF 38/311 reads (12%) | called by muse, mutect2, varscan2
- KLKB1 | c.1689T>C p.C563= | Silent (SNP) | VAF 26/210 reads (12%) | called by muse, mutect2
- LANCL3 | c.153C>A p.A51= | Silent (SNP) | VAF 16/114 reads (14%) | called by muse, mutect2, varscan2
- MAGEA4 | c.141C>A p.V47= | Silent (SNP) | VAF 18/126 reads (14%) | called by muse, mutect2, varscan2
- MYO7A | c.2163A>T p.I721= | Silent (SNP) | VAF 12/235 reads (5%) | called by muse, mutect2
- NEU2 | c.672C>T p.V224= | Silent (SNP) | VAF 13/105 reads (12%) | catalogued as rs540432557, COSV52091756; called by muse, mutect2, varscan2
- NHS | c.1462C>A p.R488= | Silent (SNP) | VAF 16/196 reads (8%) | catalogued as COSV66273100; called by muse, mutect2
- NLRP6 | c.2046G>A p.A682= | Silent (SNP) | VAF 12/83 reads (14%) | catalogued as COSV56459060; called by muse, mutect2
- NPSR1 | c.573C>A p.S191= | Silent (SNP) | VAF 34/484 reads (7%) | catalogued as COSV100705676, COSV100706354; called by muse, mutect2
- NRXN2 | c.3612T>C p.F1204= | Silent (SNP) | VAF 11/264 reads (4%) | called by muse, mutect2
- OR2A14 | c.150G>A p.L50= | Silent (SNP) | VAF 28/222 reads (13%) | called by muse, mutect2, varscan2
- PSMB9 | c.270G>T p.L90= | Silent (SNP) | VAF 11/171 reads (6%) | called by muse, mutect2
- RAD50 | c.987G>A p.L329= | Silent (SNP) | VAF 21/181 reads (12%) | catalogued as rs1223725137; called by muse, mutect2, varscan2
- RBM10 | c.2661T>C p.P887= | Silent (SNP) | VAF 14/336 reads (4%) | called by muse, mutect2
- RNF125 | c.408A>T p.A136= | Silent (SNP) | VAF 27/203 reads (13%) | called by muse, mutect2, varscan2
- SCN8A | c.2511G>T p.V837= | Silent (SNP) | VAF 17/203 reads (8%) | catalogued as COSV61990546; called by muse, mutect2
- SHMT1 | c.645G>T p.R215= | Silent (SNP) | VAF 74/697 reads (11%) | called by muse, varscan2
- SLITRK1 | c.1866G>T p.P622= | Silent (SNP) | VAF 21/200 reads (11%) | called by muse, mutect2, varscan2
- SMPD4 | c.1947C>T p.D649= (on ENST00000409031 / NM_017951.4; = p.D620= on NM_017751.4) | Silent (SNP) | VAF 32/379 reads (8%) | called by muse, mutect2
- SOST | c.576C>A p.G192= | Silent (SNP) | VAF 29/217 reads (13%) | called by muse, mutect2, varscan2
- TDRD1 | c.3345A>G p.L1115= | Silent (SNP) | VAF 16/140 reads (11%) | catalogued as rs917087933; called by muse, varscan2
- TYW1B | c.1545A>G p.A515= | Silent (SNP) | VAF 6/68 reads (9%) | catalogued as rs782534545; called by muse, mutect2
- UBA6 | c.552C>T p.I184= | Silent (SNP) | VAF 22/223 reads (10%) | called by muse, mutect2, varscan2
- UBAP2L | c.3135G>A p.Q1045= | Silent (SNP) | VAF 16/260 reads (6%) | called by muse, mutect2
- USP16 | c.1087C>T p.L363= | Silent (SNP) | VAF 17/173 reads (10%) | catalogued as rs1237390811; called by muse, mutect2
- ABI3BP | c.1063+813T>C | Intron (SNP) | VAF 22/264 reads (8%) | called by muse, mutect2
- AC109583.1 | c.-542-13714G>A | Intron (SNP) | VAF 5/72 reads (7%) | catalogued as rs1257741135; called by muse, mutect2
- AC134312.1 | n.569C>A | RNA (SNP) | VAF 10/98 reads (10%) | called by muse, mutect2
- ASAH1 | c.833+51A>G | Intron (SNP) | VAF 8/134 reads (6%) | called by muse, mutect2
- ATG2A | chr11:64891150 C>A | 3'Flank (SNP) | VAF 7/44 reads (16%) | catalogued as rs1408893511; called by muse, mutect2, varscan2
- BAIAP2 | c.280-29_280-23del | Intron (DEL) | VAF 25/340 reads (7%) | called by mutect2, pindel
- CDCA5 | c.46+81G>T | Intron (SNP) | VAF 28/291 reads (10%) | called by muse, mutect2
- CLK2P1 | n.808T>A | RNA (SNP) | VAF 42/522 reads (8%) | called by muse, mutect2
- DCHS2 | n.846A>G | RNA (SNP) | VAF 7/46 reads (15%) | called by muse, mutect2
- EDA | c.397-96086G>C | Intron (SNP) | VAF 9/77 reads (12%) | called by muse, mutect2, varscan2
- LZTR1 | c.1615+15G>T | Intron (SNP) | VAF 12/87 reads (14%) | catalogued as rs781459085, COSV53147817; called by muse, mutect2, varscan2
- MAPK1IP1L | c.-111G>T | 5'UTR (SNP) | VAF 22/321 reads (7%) | called by muse, mutect2
- MAPK1IP1L | c.-110C>T | 5'UTR (SNP) | VAF 22/322 reads (7%) | called by muse, mutect2
- MIR1302-7 | n.16G>T | RNA (SNP) | VAF 12/150 reads (8%) | called by muse, mutect2
- MIR325 | n.45C>A | RNA (SNP) | VAF 14/206 reads (7%) | called by muse, mutect2
- MIR424 | n.3A>T | RNA (SNP) | VAF 11/100 reads (11%) | called by muse, mutect2, varscan2
- NRK | c.4354-825G>T | Intron (SNP) | VAF 12/108 reads (11%) | catalogued as rs1465952007; called by muse, varscan2
- PPM1A | chr14:60245885 C>T | 5'Flank (SNP) | VAF 12/128 reads (9%) | called by muse, mutect2
- RNF170 | c.-8+60C>T | Intron (SNP) | VAF 19/196 reads (10%) | catalogued as rs1345450959; called by muse, mutect2, varscan2
- RNF180 | c.1227+17T>A | Intron (SNP) | VAF 7/55 reads (13%) | called by muse, mutect2, varscan2
- RNF213 | c.-4A>C | 5'UTR (SNP) | VAF 30/308 reads (10%) | called by muse, mutect2
- SLC6A8 | c.262+19C>A | Intron (SNP) | VAF 8/110 reads (7%) | called by muse, mutect2
- SPATA31C2 | n.2038G>T | RNA (SNP) | VAF 59/492 reads (12%) | called by muse, mutect2, varscan2
- TMCO1 | c.*953A>T | 3'UTR (SNP) | VAF 37/392 reads (9%) | called by muse, mutect2, varscan2
- TSHZ3 | c.-30G>A | 5'UTR (SNP) | VAF 14/119 reads (12%) | called by muse, mutect2, varscan2
- TTN | c.10361-5571T>G | Intron (SNP) | VAF 22/343 reads (6%) | called by muse, mutect2
- UBE2DNL | n.138T>C | RNA (SNP) | VAF 15/98 reads (15%) | catalogued as rs1569445369; called by muse, mutect2, varscan2
- ZNF185 | c.1209-3548G>T | Intron (SNP) | VAF 8/146 reads (5%) | catalogued as rs1458333727; called by muse, mutect2
